Somatic mutation profile of tumor specimen TCGA-AR-A2LL-01A (aliquot TCGA-AR-A2LL-01A-11D-A17W-09) from TCGA case TCGA-AR-A2LL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.5 years (25,747 days).
Specimen TCGA-AR-A2LL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08350a94-24a8-42fe-9810-dbe2fa87a0be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A2LL-10A (Blood Derived Normal), aliquot TCGA-AR-A2LL-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/436207c5-ca47-4c8e-9c84-c19ec78aae18

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 27, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 28/57 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD097201, CM971271, COSV64288968, COSV64294667, COSV64296578, COSV64297040; called by muse, mutect2, varscan2
- ABCA9 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as COSV60621305, COSV60623918; called by muse, mutect2, varscan2
- CCDC198 | c.329C>A p.P110Q | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775180996, COSV53601885; called by muse, mutect2, varscan2
- CD48 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs1200509561, COSV63566447; called by muse, mutect2, varscan2
- CDH1 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs943875725, CM015108, CS020997, COSV55727570, COSV55731504; called by muse, mutect2, varscan2
- CLNK | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as COSV57014235, COSV57018927; called by muse, mutect2, varscan2
- CSNK1G2 | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.02); catalogued as COSV55337016; called by muse, mutect2, varscan2
- CUBN | c.5951C>T p.T1984M | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs150924438; called by muse, mutect2, varscan2
- DDX5 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99857552; called by muse, mutect2
- EPHA2 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs754656950, COSV64452467; called by muse, mutect2
- FRMD3 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV100418666, COSV58460276; called by muse, mutect2, varscan2
- FRMD7 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 6/124 reads (5%) | catalogued as rs1043225481, CM081618, COSV53745157; called by muse, mutect2
- HERC6 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV52029460; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); catalogued as rs1383656208, COSV61154060; called by muse, mutect2, varscan2
- IRAK1BP1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV64048158; called by muse, mutect2, varscan2
- ITGA6 | c.3167T>C p.I1056T (on ENST00000442250; = p.I1017T on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV51223169; called by muse, mutect2, varscan2
- ITGAM | c.530T>C p.M177T | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54936516; called by muse, mutect2, varscan2
- KLF15 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as rs867343522, COSV56179887; called by muse, mutect2, varscan2
- MYO3B | c.3937C>T p.P1313S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.058); catalogued as COSV58701586; called by muse, mutect2, varscan2
- NUP98 | c.3510G>T p.Q1170H (on ENST00000359171 / NM_001365126.1; = p.Q1153H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV61431459; called by muse, mutect2, varscan2
- OR8K3 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs200418517, COSV57130852; called by muse, mutect2
- RAPGEF4 | c.2482G>A p.V828I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs575529555, COSV51383834; called by muse, mutect2, varscan2
- RAPGEF6 | c.1771T>G p.F591V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV57245108; called by muse, mutect2, varscan2
- RHOT2 | c.1309C>T p.L437F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs767192667, COSV99552579; called by muse, mutect2
- SIRPB2 | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV100708635, COSV63123566; called by muse, mutect2, varscan2
- TRDC | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as rs759332805; called by muse, mutect2, varscan2
- TUBA3C | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.364); catalogued as rs752908038, COSV68028193; called by muse, mutect2, varscan2
- WDR25 | c.685T>C p.Y229H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV58935987; called by muse, mutect2, varscan2
- GRPR | c.819C>T p.F273= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs764794635, COSV66669220; called by muse, mutect2, varscan2
- MTCL1 | c.2358G>A p.S786= (on ENST00000306329 / NM_001378206.1; = p.S426= on NM_015210.4) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs569419751, COSV60405500; called by muse, mutect2, varscan2
- PDGFRB | c.1788G>A p.P596= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs781338234, COSV99940087; called by muse, mutect2
- TIMM44 | c.810C>T p.N270= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs139986376; called by muse, mutect2, varscan2
